Somatic mutation profile of tumor specimen TCGA-75-7025-01A (aliquot TCGA-75-7025-01A-12D-1945-08) from TCGA case TCGA-75-7025, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-7025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f9f350b-96b1-4e90-a103-624ab3289891.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-7025-10A (Blood Derived Normal), aliquot TCGA-75-7025-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67929cd7-8ce6-4fae-b44e-9c123366666e

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 16, Silent 11, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 28/84 reads (33%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TBC1D24 | c.1544C>T p.A515V (on ENST00000646147 / NM_001199107.2; = p.A509V on NM_020705.3) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607105, CM105652, COSV53546654; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AC127029.3 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1567803095, CM113628, COSV60111076; called by muse, mutect2, varscan2
- CACNG3 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV50070125; called by muse, mutect2, varscan2
- CHD9 | c.6980A>G p.H2327R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV54611444; called by muse, mutect2
- CTNNA2 | c.849T>G p.F283L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.327); catalogued as COSV63573544; called by muse, mutect2, varscan2
- DMBT1 | c.7175C>T p.S2392L (on ENST00000338354 / NM_001377530.1; = p.S1635L on NM_004406.3) | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.591); catalogued as COSV57539137; called by muse, mutect2
- EMC2 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV55209502; called by muse, mutect2, varscan2
- GAPT | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV100576334; called by muse, mutect2, varscan2
- GYG1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.589); catalogued as COSV56049996; called by muse, mutect2, varscan2
- HECW1 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs760145989, COSV67831352; called by muse, mutect2, varscan2
- IBTK | c.884A>C p.H295P | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60393433; called by muse, mutect2
- KIF14 | c.2814-1G>A p.X938_splice | Splice Site (SNP) | VAF 7/95 reads (7%) | catalogued as COSV66262104; called by muse, mutect2
- KTN1 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375858500, COSV68023813; called by muse, mutect2, varscan2
- MMP19 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59451700; called by muse, mutect2, varscan2
- NFKB1 | c.1308C>A p.D436E (on ENST00000394820 / NM_001382627.1; = p.D437E on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV56957292; called by muse, mutect2, varscan2
- NTNG1 | c.1464C>G p.C488W (on ENST00000370068 / NM_001113226.3; = p.C387W on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64272730; called by muse, mutect2
- RSC1A1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.677); catalogued as rs759773926, COSV60779966; called by muse, mutect2, varscan2
- SETD2 | c.3651G>A p.W1217* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV57439760, COSV57456184; called by muse, mutect2, varscan2
- TAP2 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs774034040, COSV66499594; called by muse, mutect2, varscan2
- MYO7B | c.2939dup p.Y980* | Nonsense Mutation (INS) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- SETD2 | c.6297_6301del p.D2100Tfs*4 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- CSMD2 | c.2121C>T p.L707= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs750389901, COSV53919876; called by muse, mutect2, varscan2
- CYP2C9 | c.1183C>T p.L395= | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as rs1183098927, COSV53249544; called by muse, mutect2
- DAXX | c.2208C>T p.L736= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs755206233, COSV56470133; called by muse, mutect2, varscan2
- INPP4B | c.1083C>T p.Y361= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs528311267, COSV53728788; called by muse, mutect2, varscan2
- JPH3 | c.540C>T p.D180= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs758856596, COSV52465625; called by muse, mutect2
- LRFN3 | c.504C>T p.L168= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs760768387, COSV55817996; called by muse, mutect2, varscan2
- MAGEC3 | c.255C>T p.F85= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV53581466; called by muse, mutect2
- MARCHF1 | c.255C>T p.C85= (on ENST00000274056; = p.C68= on NM_017923.4) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs776363990, COSV56812512, COSV56819636; called by muse, varscan2
- PLVAP | c.963G>A p.A321= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs150210307; called by muse, mutect2, varscan2
- SH3TC1 | c.2994C>T p.A998= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs141442802; called by muse, mutect2, varscan2
- SMARCAD1 | c.2361A>G p.L787= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100758985; called by muse, mutect2, varscan2
